Gene-level copy-number profile of tumor specimen SM-JU33Z from CPTAC case C219555, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen SM-JU33Z: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 312657bd-f601-4ad1-a324-052972327904.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105285 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/d728aef1-e6e8-4185-89db-a3d21a159f0a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 10,960; copy number 2: 45,449; copy number 3: 2,328; copy number 4: 35; copy number 5: 30; copy number 7: 6; copy number 24: 3; copy number 25: 4; copy number 31: 22; copy number 43: 2; copy number 58: 6.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,994,139–22,128,103, 1 gene (within-gene range 0–1): CDKN2B-AS1.
- chr9:22,046,758–23,438,700, 8 genes: AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:23,829,670–26,644,595, 12 genes: AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1.
- chr9:27,245,680–31,166,980, 31 genes: LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1.
- chr9:32,293,558–32,454,769, 3 genes: RNA5SP281, SLC25A5P8, ACO1.
- chr14:20,640,696–20,641,691, 1 gene: OR6S1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 73 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:26,152,198–26,995,239, 13 genes, copy number 5–7 (within-gene range 3–7): NFE2L3, HNRNPA2B1, CBX3, AC010677.1, SNX10, AC004540.2, AC004540.1, KIAA0087, AC004947.2, AC004947.1, LINC02860, SKAP2, RPL7AP38.
- chr7:53,926,676–56,323,601, 60 genes, copy number 5–58: LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2, IFITM3P4, AC006970.1, CCNJP1, AC073136.1, AC073136.2, AC093392.1.

Autosomal genes at a single copy (total copy number 1): 8,104. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
